Somatic mutation profile of tumor specimen TCGA-BF-AAP2-01A (aliquot TCGA-BF-AAP2-01A-11D-A401-08) from TCGA case TCGA-BF-AAP2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.2 years (22,734 days).
Specimen TCGA-BF-AAP2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06567117-c9eb-4551-80c8-71a30dc4193d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP2-10A (Blood Derived Normal), aliquot TCGA-BF-AAP2-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98989161-4d01-4023-8b2f-9bc96b039071

The open-access MAF lists 1,616 somatic variants for this specimen: 1,045 protein-altering or splice-affecting, 523 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 945, Silent 523, Nonsense Mutation 64, Intron 28, Splice Region 17, Splice Site 11, RNA 8, 3'UTR 7, 5'Flank 4, Translation Start Site 3, In Frame Del 2, Frame Shift Ins 2.

Variants (750 of 1,616; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 72/171 reads (42%) | catalogued as rs1085307773, COSV59101172; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 97/138 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912475, COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- LDLR | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs144172724, CD045103, CM920408, CM950751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MATR3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs587777302, CM146315, COSV100735222; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 60/127 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SEMA4B | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 5/9 reads (56%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs1406627528, COSV60173432; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 24/47 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.4411C>T p.L1471F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1408834197, COSV100588709; called by muse, mutect2, varscan2
- AADAT | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1216507753, COSV100528648; called by muse, mutect2, varscan2
- ABCA10 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99288685; called by muse, mutect2, varscan2
- ABCA13 | c.5206C>T p.P1736S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101330057; called by muse, mutect2, varscan2
- ABCA2 | c.2645C>T p.S882F (on ENST00000614293; = p.S852F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99687748; called by muse, mutect2
- ABCA4 | c.6298G>A p.G2100R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64674298; called by muse, mutect2, varscan2
- ABCC12 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100252743; called by muse, mutect2, varscan2
- ABCD2 | c.992A>T p.N331I | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV100429519; called by muse, mutect2
- AC005324.2 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV100371918; called by muse, mutect2, varscan2
- AC008397.2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.24); catalogued as COSV53205143, COSV99441752; called by muse, varscan2
- AC100868.1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.236); catalogued as COSV51840631; called by muse, mutect2, varscan2
- ACAP1 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99341706; called by muse, mutect2, varscan2
- ACO1 | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV59385849; called by muse, mutect2, varscan2
- ACTBL2 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.918); catalogued as COSV101379353; called by muse, mutect2, varscan2
- ACTL6B | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.793); catalogued as COSV99355586; called by muse, mutect2, varscan2
- ACVRL1 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV66360462; called by muse, mutect2, varscan2
- ADAM18 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV99695631; called by muse, mutect2, varscan2
- ADAM19 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332076059, COSV99976509; called by muse, mutect2
- ADAM32 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.786); catalogued as rs957652162, COSV65950171; called by muse, mutect2, varscan2
- ADAM9 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV65962066; called by muse, mutect2, varscan2
- ADAMTS12 | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as rs750306160, COSV100711039; called by muse, mutect2, varscan2
- ADAMTS18 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV51403092; called by muse, mutect2, varscan2
- ADAMTS19 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50807614; called by muse, mutect2, varscan2
- ADAMTS3 | c.3205C>T p.H1069Y | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV99711193; called by muse, mutect2, varscan2
- ADAMTS6 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV58685289; called by muse, mutect2, varscan2
- ADAMTS9 | c.2897G>A p.S966N | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99899524; called by muse, mutect2, varscan2
- ADAP2 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100437256; called by muse, mutect2, varscan2
- ADCY1 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99812102; called by muse, mutect2, varscan2
- ADCY10 | c.2740C>T p.R914C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs144433453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY10 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as COSV100896893; called by muse, mutect2, varscan2
- ADD3 | c.1732+2T>C p.X578_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99523455; called by muse, mutect2, varscan2
- ADGRB3 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65391017; called by muse, mutect2, varscan2
- ADGRE1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1366583656, COSV51672721, COSV99165755; called by muse, mutect2, varscan2
- ADGRG2 | c.920C>T p.S307L (on ENST00000379869 / NM_001079858.3; = p.S304L on NM_005756.4) | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.394); catalogued as rs761433588, COSV100492300; called by muse, mutect2, varscan2
- ADGRG3 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.302); catalogued as rs201334045; called by muse, mutect2, varscan2
- ADGRG4 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs914911331, COSV99795641; called by muse, mutect2, varscan2
- ADGRV1 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67981881; called by muse, mutect2, varscan2
- ADGRV1 | c.6064G>A p.E2022K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV101316054; called by muse, mutect2, varscan2
- ADGRV1 | c.14666G>A p.G4889E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101316056; called by muse, mutect2, varscan2
- ADH1A | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99265801; called by muse, mutect2, varscan2
- AFMID | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100014978; called by muse, mutect2, varscan2
- AGBL1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV101223253; called by muse, mutect2, varscan2
- AGTPBP1 | c.1826C>T p.S609L (on ENST00000357081 / NM_001330701.2; = p.S569L on NM_015239.2) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100429813; called by muse, mutect2, varscan2
- AGTR1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 67/167 reads (40%) | catalogued as rs1417391173, COSV62557140; called by muse, mutect2, varscan2
- AHCYL2 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1220661797, COSV100273438; called by muse, mutect2, varscan2
- AHNAK | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs368707493; called by muse, mutect2, varscan2
- AHNAK | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs745885352, COSV99947730; called by muse, mutect2, varscan2
- AIFM3 | c.723C>T p.S241= | Splice Region (SNP) | VAF 37/87 reads (43%) | catalogued as COSV58999191; called by muse, mutect2, varscan2
- AKAP11 | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99213972; called by muse, mutect2, varscan2
- AKAP6 | c.6285G>T p.L2095F | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99801262; called by muse, mutect2, varscan2
- AKR1B10 | c.66G>A p.K22= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as rs749890611, COSV100610166; called by muse, mutect2, varscan2
- AKR1B10 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV100610196; called by muse, mutect2, varscan2
- AKR1C3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs782758217, COSV101003092; called by muse, mutect2, varscan2
- AMER3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV58466773; called by muse, mutect2, varscan2
- ANAPC1 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs1417055822, COSV100594494; called by muse, mutect2, varscan2
- ANGPTL1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | catalogued as rs1238253851, COSV52367235, COSV99328195; called by muse, mutect2, varscan2
- ANGPTL5 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV57532392; called by muse, mutect2
- ANK3 | c.5518C>T p.P1840S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.07); catalogued as COSV55081231; called by muse, mutect2, varscan2
- ANK3 | c.4385C>T p.S1462F (on ENST00000280772 / NM_001320874.2; = p.S587F on NM_001149.3) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV99780205; called by muse, mutect2, varscan2
- ANKIB1 | c.1982A>G p.K661R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.527); catalogued as rs1460846155, COSV99729165; called by muse, mutect2, varscan2
- ANKRD30A | c.511-1G>A p.X171_splice (on ENST00000611781; = p.X115_splice on NM_052997.2) | Splice Site (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100652956, COSV64609404; called by muse, mutect2, varscan2
- ANKRD45 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100322515; called by muse, mutect2, varscan2
- ANO2 | c.610C>T p.P204S (on ENST00000356134 / NM_001278597.3; = p.P208S on NM_001278596.3) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59006036; called by muse, mutect2, varscan2
- AP1S3 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1559279532, COSV100525479, COSV57512983; called by muse, mutect2, varscan2
- AP2B1 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV99251302; called by muse, mutect2, varscan2
- APBB1IP | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63302092; called by muse, mutect2, varscan2
- APBB1IP | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766226916, COSV100770898, COSV63076537; called by muse, mutect2, varscan2
- APC | c.6684G>T p.R2228S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57337446, COSV57390303; called by muse, mutect2, varscan2
- APOB | c.8804G>A p.R2935K | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99265877; called by muse, mutect2, varscan2
- ARAP2 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100394723; called by muse, mutect2, varscan2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2, varscan2
- AREL1 | c.2404T>G p.Y802D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100707617; called by muse, mutect2, varscan2
- ARHGAP29 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV53110737; called by muse, mutect2, varscan2
- ARHGAP39 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.335); catalogued as rs1369544215; called by muse, mutect2
- ARHGEF15 | c.936G>A p.G312= | Splice Region (SNP) | VAF 52/98 reads (53%) | catalogued as rs138318077, COSV62724556, COSV62726392; called by muse, mutect2, varscan2
- ARHGEF15 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.651); catalogued as COSV100730055, COSV62724935; called by muse, mutect2, varscan2
- ARHGEF4 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV58126037; called by muse, mutect2, varscan2
- ARID2 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 44/105 reads (42%) | catalogued as COSV100536310; called by muse, mutect2, varscan2
- ARSF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV100839521; called by muse, mutect2
- ASMT | c.763C>T p.H255Y (on ENST00000381229; = p.H283Y on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101172471; called by muse, mutect2, varscan2
- ATG16L1 | c.954C>T p.F318= (on ENST00000392017 / NM_030803.7; = p.F299= on NM_017974.4) | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as rs776787304, COSV61464859; called by muse, mutect2, varscan2
- ATP10B | c.4357C>T p.R1453C | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs755656828, COSV59165460; called by muse, mutect2, varscan2
- ATP13A5 | c.2320-1G>A p.X774_splice | Splice Site (SNP) | VAF 28/82 reads (34%) | catalogued as COSV100665206; called by muse, mutect2, varscan2
- ATP7B | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.029); catalogued as rs370961504; called by muse, mutect2, varscan2
- ATP8B4 | c.3493A>T p.N1165Y | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99465751; called by muse, mutect2, varscan2
- ATRX | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 176/201 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782314240, COSV64879574; called by muse, mutect2, varscan2
- BAIAP2 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1420880639, COSV100348191; called by muse, mutect2, varscan2
- BCL11A | c.1973C>T p.S658L (on ENST00000335712 / NM_001365609.1; = p.S692L on NM_018014.4) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1180503162, COSV100185756; called by muse, mutect2, varscan2
- BHLHE40 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.049); catalogued as COSV99848167; called by muse, mutect2, varscan2
- BIRC3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815323; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4634C>T p.T1545I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.987); catalogued as rs1160663201, COSV100863780; called by muse, mutect2, varscan2
- BLK | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52049054; called by muse, mutect2, varscan2
- BLNK | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as COSV99813941; called by muse, mutect2, varscan2
- BMP2 | c.938G>A p.W313* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs867664596, COSV101122091; called by muse, mutect2, varscan2
- BMPER | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.622); catalogued as COSV99779712, COSV99780801; called by muse, mutect2, varscan2
- BMPER | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs1482812474, COSV99779714; called by muse, mutect2, varscan2
- BOD1L1 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99239474; called by muse, mutect2, varscan2
- BRCA1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886037990, COSV100524285, COSV58784706, COSV58788589; ClinVar: uncertain significance; called by muse, mutect2
- BRINP1 | c.1824G>A p.W608* | Nonsense Mutation (SNP) | VAF 39/94 reads (41%) | catalogued as COSV56297934; called by muse, mutect2, varscan2
- BRINP2 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100838103, COSV100838109; called by muse, mutect2, varscan2
- BTBD11 | c.2332G>A p.A778T (on ENST00000280758 / NM_001018072.2; = p.A315T on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99775967; called by muse, mutect2, varscan2
- BTNL3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61564826; called by muse, mutect2, varscan2
- BTNL8 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV99180482; called by muse, mutect2, varscan2
- BUB3 | c.17A>T p.E6V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100378774; called by muse, mutect2, varscan2
- C16orf46 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1567575313, COSV100215339; called by muse, mutect2, varscan2
- C2orf78 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101280978; called by muse, mutect2, varscan2
- C2orf78 | c.2530C>T p.Q844* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV68519428; called by muse, mutect2, varscan2
- C3orf56 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV101228961; called by muse, mutect2, varscan2
- C3orf56 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371883407; called by muse, mutect2, varscan2
- C5AR1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs199646949, COSV100754029; called by muse, mutect2, varscan2
- C5AR2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.39); catalogued as COSV99953763; called by muse, mutect2, varscan2
- C6 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773561042, COSV54708983, COSV99667191; called by muse, mutect2, varscan2
- C8orf34 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs868113803, COSV61381717; called by muse, mutect2, varscan2
- C9 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV54674509; called by muse, mutect2, varscan2
- C9orf131 | c.2978A>G p.Q993R | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100398128; called by muse, mutect2, varscan2
- CA2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs143666045; called by muse, mutect2, varscan2
- CAB39L | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771642266, COSV61716924; called by muse, mutect2, varscan2
- CACNA1F | c.5051G>A p.G1684E | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100544917; called by muse, mutect2, varscan2
- CACNA1G | c.5765C>T p.S1922F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs763517294, COSV61730428; called by muse, mutect2, varscan2
- CACNA2D3 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1384932664, COSV55587618; called by muse, mutect2, varscan2
- CACNA2D4 | c.3146A>G p.N1049S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99765755; called by muse, mutect2, varscan2
- CADM3 | c.547C>T p.P183S (on ENST00000368125 / NM_001127173.3; = p.P217S on NM_021189.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.06); catalogued as rs191216919, COSV63684125; called by muse, mutect2, varscan2
- CALCR | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as rs1364388497, COSV100810565; called by muse, mutect2, varscan2
- CATSPERZ | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99134624; called by muse, mutect2
- CBLB | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99913540; called by muse, mutect2, varscan2
- CCAR2 | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV99254610; called by muse, mutect2, varscan2
- CCDC113 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.317); catalogued as rs1400547103, COSV99540978; called by muse, mutect2, varscan2
- CCDC39 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99869102; called by muse, mutect2
- CCDC88B | c.1925G>A p.R642K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1041495704, COSV100105470; called by muse, mutect2
- CCKAR | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55164495; called by muse, mutect2, varscan2
- CD109 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs201376556, COSV54657755; called by muse, mutect2, varscan2
- CD163 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775867; called by muse, mutect2, varscan2
- CD163L1 | c.3949G>A p.G1317R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58016418; called by muse, mutect2, varscan2
- CD1E | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as COSV63770174; called by muse, mutect2, varscan2
- CD1E | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs754722731, COSV63771196; called by muse, mutect2
- CD2AP | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100830434; called by muse, mutect2, varscan2
- CD300C | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs759311056, COSV100423256; called by muse, mutect2, varscan2
- CD8B | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100514540, COSV58926978; called by muse, mutect2, varscan2
- CD99 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs745720510, COSV101152294; called by muse, mutect2, varscan2
- CDC42EP2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54203408; called by muse, mutect2, varscan2
- CDH10 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100051700; called by muse, mutect2, varscan2
- CDH15 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.515); catalogued as rs1419856684, COSV57025343; called by muse, mutect2, varscan2
- CDH23 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs758451585, COSV99821257; called by muse, mutect2, varscan2
- CDK14 | c.508G>A p.E170K (on ENST00000380050 / NM_001287135.2; = p.E152K on NM_012395.3) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV56053009; called by muse, mutect2, varscan2
- CDK8 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV101037293; called by muse, mutect2, varscan2
- CDYL2 | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs762047020, COSV101629574; called by muse, mutect2, varscan2
- CEACAM16 | c.1110G>A p.W370* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV101312706; called by muse, mutect2, varscan2
- CELSR1 | c.7144G>A p.E2382K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.582); catalogued as rs764728994, COSV99418487; called by muse, mutect2, varscan2
- CEMIP | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1417995800, COSV99586801; called by muse, mutect2, varscan2
- CEMIP | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV99586803, COSV99587489; called by muse, mutect2, varscan2
- CENPJ | c.2791C>T p.R931C | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199749446, COSV101121517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP162 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs374584686; called by muse, mutect2, varscan2
- CFAP100 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 113/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100729256; called by muse, mutect2, varscan2
- CFAP20DC | c.1246C>T p.P416S (on ENST00000482387 / NM_001351530.2; = p.P291S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs1257788256, COSV99918829; called by muse, mutect2, varscan2
- CFAP54 | c.4960C>T p.L1654F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.565); catalogued as COSV100733194; called by muse, mutect2, varscan2
- CFAP54 | c.7400G>A p.G2467E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as COSV100733196; called by muse, mutect2, varscan2
- CFAP70 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV100160643; called by muse, mutect2, varscan2
- CFAP70 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772771453, COSV100160644, COSV60281927; called by muse, mutect2, varscan2
- CHRM3 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.069); catalogued as rs755384239, COSV55101431, COSV99697289; called by muse, mutect2, varscan2
- CHRNB3 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV51495365; called by muse, mutect2, varscan2
- CHRNG | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101263959; called by muse, mutect2, varscan2
- CIBAR2 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV101608278, COSV73320707; called by muse, mutect2, varscan2
- CKMT2 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1281926764, COSV99562398; called by muse, mutect2, varscan2
- CLSTN1 | c.836G>T p.G279V (on ENST00000377298 / NM_001009566.3; = p.G269V on NM_014944.4) | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790587; called by muse, mutect2, varscan2
- CNKSR1 | c.1031C>T p.S344F (on ENST00000374253 / NM_001297647.2; = p.S337F on NM_006314.3) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs867995657, COSV100836744; called by muse, mutect2, varscan2
- CNKSR1 | c.1519C>T p.P507S (on ENST00000374253 / NM_001297647.2; = p.P500S on NM_006314.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV100128410; called by muse, mutect2, varscan2
- CNN2 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV54045413, COSV99567752; called by muse, mutect2, varscan2
- CNNM3 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs372666354; called by muse, mutect2, varscan2
- CNTN1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61641913; called by muse, mutect2, varscan2
- CNTN5 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1436874415, COSV54275052, COSV99681181; called by muse, mutect2
- CNTNAP4 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs1245559508, COSV100269286; called by muse, mutect2, varscan2
- CNTNAP5 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101443624, COSV70502255; called by muse, mutect2, varscan2
- COL15A1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.018); catalogued as COSV100897749; called by muse, mutect2, varscan2
- COL28A1 | c.1860G>A p.K620= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101258632, COSV68085198; called by muse, mutect2, varscan2
- COL28A1 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs368227356; called by muse, mutect2, varscan2
- COL4A2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100847362; called by muse, mutect2
- COL4A5 | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60366234; called by muse, mutect2, varscan2
- COL5A2 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV66408648; called by muse, mutect2, varscan2
- COL5A2 | c.3349A>C p.K1117Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.892); catalogued as COSV100880393; called by muse, mutect2, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- CPAMD8 | c.2258G>A p.R753Q (on ENST00000651564; = p.R706Q on NM_015692.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs777970187, COSV99359432; called by muse, mutect2, varscan2
- CPEB1 | c.281G>A p.R94Q (on ENST00000617958; = p.R34Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs751474815, COSV101477627; called by muse, mutect2, varscan2
- CPNE4 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV101456723; called by muse, mutect2, varscan2
- CRACR2A | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99365061; called by muse, mutect2, varscan2
- CREB3L1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1225993766, COSV55830486; called by muse, mutect2, varscan2
- CREG2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100240487, COSV100240606; called by muse, mutect2, varscan2
- CRISP1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100236909, COSV59993909; called by muse, mutect2, varscan2
- CROT | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV100519535; called by muse, mutect2, varscan2
- CRYBA2 | c.590A>G p.H197R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1315153015, COSV99837917; called by muse, mutect2, varscan2
- CRYBB1 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as COSV53234615; called by muse, mutect2, varscan2
- CSF2RB | c.2294G>A p.G765D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99453933; called by muse, mutect2, varscan2
- CSMD1 | c.6595G>A p.D2199N (on ENST00000520002; = p.D2198N on NM_033225.6) | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1339389309, COSV59299379; called by muse, mutect2, varscan2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- CSMD3 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52244125; called by muse, mutect2, varscan2
- CSMD3 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 40/97 reads (41%) | catalogued as COSV52241410, COSV99835832; called by muse, mutect2, varscan2
- CST8 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as COSV55671970, COSV99849982; called by muse, mutect2, varscan2
- CTAGE1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV101194555; called by muse, mutect2, varscan2
- CTNNA2 | c.2816C>T p.S939L (on ENST00000402739 / NM_001282597.3; = p.S891L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1052098013, COSV58132864; called by muse, mutect2, varscan2
- CTSE | c.1042-1G>A p.X348_splice (on ENST00000360218; = p.X343_splice on NM_001910.4) | Splice Site (SNP) | VAF 22/154 reads (14%) | catalogued as COSV63061271; called by muse, mutect2, varscan2
- CUX2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.617); catalogued as rs1306585496, COSV99919806; called by muse, mutect2, varscan2
- CXorf66 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs747755412, COSV100983812, COSV65169783; called by muse, mutect2, varscan2
- CYLC1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs1007098949, COSV100254733; called by muse, mutect2, varscan2
- CYP19A1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1421012793, COSV53057324, COSV53060302; called by muse, mutect2, varscan2
- CYP26B1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359914942, COSV50012745; called by muse, mutect2, varscan2
- CYP2C19 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.845); catalogued as rs1196078753, COSV64907829; called by muse, mutect2, varscan2
- CYP2C9 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99582768; called by muse, mutect2, varscan2
- CYP2D6 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.251); catalogued as COSV100637318; called by muse, mutect2, varscan2
- CYP3A7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60481634; called by muse, mutect2, varscan2
- CYP4B1 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV54723115, COSV99596965; called by muse, mutect2, varscan2
- CYP4B1 | c.1353G>A p.R451= | Splice Region (SNP) | VAF 23/70 reads (33%) | catalogued as COSV54727033; called by muse, mutect2, varscan2
- D2HGDH | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100344513; called by muse, mutect2, varscan2
- DAB1 | c.1606C>T p.P536S (on ENST00000371231; = p.P503S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100976374; called by muse, mutect2, varscan2
- DAO | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs370409180; called by muse, mutect2, varscan2
- DBH | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs373889996; called by mutect2, varscan2
- DCAF4L2 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100150931, COSV60477341; called by muse, mutect2, varscan2
- DDO | c.704G>A p.G235E (on ENST00000368924 / NM_001368172.1; = p.G176E on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927867; called by muse, mutect2, varscan2
- DDX51 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs769159441, COSV57958374; called by muse, mutect2, varscan2
- DDX60L | c.3148A>G p.R1050G | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1302592120, COSV99487687; called by muse, mutect2, varscan2
- DEFB118 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as rs868821162, COSV99489216; called by muse, mutect2, varscan2
- DENND4C | c.4091C>T p.P1364L (on ENST00000434457 / NM_001330640.2; = p.P1315L on NM_017925.7) | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100727453; called by muse, mutect2, varscan2
- DERA | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101397399; called by mutect2, varscan2
- DEUP1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV99977191; called by muse, mutect2
- DGCR2 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.227); catalogued as COSV99593654; called by muse, mutect2, varscan2
- DHRS7B | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs200571409, COSV100683974; called by muse, mutect2, varscan2
- DHRS7C | c.337G>A p.E113K (on ENST00000330255 / NM_001220493.2; = p.E112K on NM_001105571.3) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57653269; called by muse, mutect2, varscan2
- DIDO1 | c.6397C>T p.R2133W | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99825613; called by muse, mutect2
- DLGAP4 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1406360453, COSV100211317; called by muse, mutect2
- DLGAP5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs373355292; called by muse, mutect2, varscan2
- DLL1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.276); catalogued as COSV100816087; called by muse, mutect2, varscan2
- DMBT1 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100353121; called by muse, mutect2, varscan2
- DMGDH | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99669062; called by muse, mutect2, varscan2
- DNAH10 | c.3064G>A p.D1022N (on ENST00000409039; = p.D961N on NM_207437.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101292305; called by muse, mutect2, varscan2
- DNAH11 | c.2329C>T p.L777F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as rs1163253626, COSV60993874; called by muse, mutect2, varscan2
- DNAH17 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV101102879, COSV67755172; called by muse, mutect2, varscan2
- DNAH2 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV101209368; called by muse, mutect2, varscan2
- DNAH2 | c.5046G>A p.M1682I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1011588300, COSV101209369; called by muse, mutect2
- DNAH2 | c.9163G>A p.E3055K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV66728206; called by muse, mutect2, varscan2
- DNAH5 | c.12454G>A p.D4152N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs761422282, COSV54226224, COSV54257014; called by muse, mutect2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 37/81 reads (46%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2, varscan2
- DNAH5 | c.7825C>T p.P2609S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as COSV54251510; called by muse, mutect2, varscan2
- DNAH7 | c.10550G>A p.R3517Q | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372792080; called by muse, mutect2, varscan2
- DNAJC10 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99899307; called by muse, mutect2, varscan2
- DNAJC13 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99607346; called by muse, mutect2, varscan2
- DNAJC16 | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101012583; called by muse, mutect2, varscan2
- DNM3 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV100798321; called by muse, mutect2, varscan2
- DNM3 | c.687G>A p.R229= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100798322; called by muse, mutect2, varscan2
- DOCK2 | c.3362G>A p.R1121K | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs748822032, COSV56940585; called by muse, mutect2, varscan2
- DOCK2 | c.3728C>T p.T1243M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56939153, COSV56983711; called by muse, mutect2, varscan2
- DOCK9 | c.4569C>T p.V1523= (on ENST00000376460 / NM_001366676.2; = p.V1524= on NM_015296.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/9 reads (44%) | catalogued as rs1395535454, COSV100239441; called by muse, mutect2
- DOP1B | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV101215451; called by muse, mutect2, varscan2
- DPP6 | c.2260G>A p.E754K (on ENST00000377770 / NM_001364500.2; = p.E692K on NM_001936.5) | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59624369; called by muse, mutect2, varscan2
- DPRX | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100934084; called by muse, mutect2, varscan2
- DPYS | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037103; called by muse, mutect2, varscan2
- DPYSL3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100575148; called by muse, mutect2, varscan2
- DRC3 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100572739; called by muse, varscan2
- DSC3 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV64572109; called by muse, mutect2, varscan2
- DSC3 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100844610; called by muse, mutect2, varscan2
- DSG1 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs867317422, COSV57138094; called by muse, mutect2, varscan2
- DSG4 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768691954, COSV57388964; called by muse, mutect2, varscan2
- DSG4 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100355949; called by muse, mutect2, varscan2
- DSP | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs762464083, COSV101131317; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- DUSP16 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs772329969, COSV99963171; called by muse, mutect2, varscan2
- DYNC2I1 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101337686; called by muse, mutect2, varscan2
- DYRK2 | c.1445C>T p.S482F (on ENST00000344096 / NM_006482.3; = p.S409F on NM_003583.4) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59846869; called by muse, mutect2, varscan2
- EBF2 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as rs1284467154, COSV101282197; called by muse, mutect2, varscan2
- EBF2 | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV101282198; called by muse, mutect2, varscan2
- EBF2 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs929126805, COSV68777879, COSV68780927; called by muse, mutect2, varscan2
- ECI2 | c.374C>T p.S125F (on ENST00000380118 / NM_206836.3; = p.S95F on NM_006117.2) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100326497; called by muse, mutect2, varscan2
- EDIL3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as rs752603385, COSV56901771; called by muse, mutect2, varscan2
- EFCAB5 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV100300287; called by muse, mutect2, varscan2
- EFHC1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV64137205; called by muse, mutect2, varscan2
- EFL1 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99187161; called by muse, mutect2, varscan2
- EHD2 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1433818542, COSV54407067; called by muse, mutect2, varscan2
- EIF4G1 | c.1336C>T p.P446S (on ENST00000346169 / NM_198241.3; = p.P250S on NM_004953.5) | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100071857; called by muse, mutect2
- EIF4G3 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51697868; called by muse, mutect2
- ELAPOR1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100884438; called by muse, mutect2, varscan2
- ELFN2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV101297555; called by muse, mutect2, varscan2
- ENAM | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.961); catalogued as COSV68537209; called by muse, mutect2, varscan2
- ENPP2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50026736, COSV99308379; called by muse, mutect2
- ENTPD2 | c.797G>A p.W266* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs866672782, COSV100445793; called by muse, mutect2, varscan2
- EPB41L1 | c.2389G>A p.G797S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs746621229, COSV52434428; called by muse, mutect2, varscan2
- EPB41L2 | c.2216C>T p.S739F | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100440826; called by muse, mutect2, varscan2
- EPHA1 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs1483496235, COSV99314053; called by muse, mutect2, varscan2
- EPHA4 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1218746876, COSV56040644; called by muse, mutect2, varscan2
- EPHB2 | c.2202G>A p.M734I (on ENST00000400191 / NM_001309193.2; = p.M735I on NM_004442.7) | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101007124, COSV65860383; called by muse, mutect2, varscan2
- EPN3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1286915901, COSV99277011; called by muse, mutect2, varscan2
- EPPK1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs782779488, COSV73261735; called by muse, mutect2, varscan2
- ERH | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV99220443; called by muse, mutect2, varscan2
- ERMP1 | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868059008, COSV53037213; called by muse, mutect2, varscan2
- ERN2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758739777, COSV56831585; called by muse, mutect2, varscan2
- F8 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.386); catalogued as COSV100811566; called by muse, mutect2, varscan2
- FAM124A | c.710C>T p.S237F (on ENST00000322475 / NM_001242312.2; = p.S273F on NM_145019.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs868846047, COSV54476203; called by muse, mutect2, varscan2
- FAM135B | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424364, COSV99425336; called by muse, mutect2, varscan2
- FAM13C | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.88); catalogued as rs1405045594, COSV99513958; called by muse, mutect2, varscan2
- FAM155A | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101028316; called by muse, mutect2
- FAM170A | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1427313521, COSV58926105; called by muse, mutect2, varscan2
- FAM91A1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58235410; called by muse, mutect2
- FAM91A1 | c.1278+2T>C p.X426_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100593616; called by muse, mutect2
- FAT1 | c.1791T>A p.D597E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101499387; called by muse, mutect2, varscan2
- FBN2 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866719857, COSV52499675, COSV52517342, COSV99331150; called by muse, mutect2, varscan2
- FBN2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs750697815, COSV104390156, COSV99327880; called by muse, mutect2, varscan2
- FBXO39 | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 28/39 reads (72%) | catalogued as COSV58623310; called by muse, mutect2, varscan2
- FBXO46 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.897); catalogued as COSV100480224; called by muse, mutect2, varscan2
- FCMR | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65567255, COSV65567643; called by muse, mutect2, varscan2
- FCRL1 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs756244171, COSV63827376; called by muse, mutect2
- FCRL1 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100839797, COSV63828123; called by muse, mutect2, varscan2
- FCRL1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100839798; called by muse, mutect2, varscan2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, mutect2, varscan2
- FGF11 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1405632678, COSV53441363; called by muse, mutect2, varscan2
- FGF16 | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV101466319, COSV71546261; called by muse, mutect2, varscan2
- FGF6 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57404316, COSV99960267; called by muse, mutect2, varscan2
- FGFR3 | c.*1087C>T | Splice Region (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99602148; called by muse, mutect2, varscan2
- FKBP6 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99333995; called by muse, mutect2, varscan2
- FLG | c.11404G>A p.G3802R | Missense Mutation (SNP) | VAF 61/433 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1470647385, COSV100911623; called by muse, mutect2, varscan2
- FLG | c.11048G>A p.G3683E | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.428); catalogued as COSV100911624; called by muse, mutect2, varscan2
- FLG2 | c.4262G>A p.G1421E | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV66167618, COSV66170289; called by muse, mutect2
- FLNC | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57960228; called by muse, mutect2, varscan2
- FLYWCH2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV53559011; called by muse, mutect2, varscan2
- FMN2 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs745830094, COSV100145396; called by muse, mutect2, varscan2
- FMNL1 | c.3021G>A p.W1007* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs1309933440, COSV58957082; called by muse, mutect2, varscan2
- FMO4 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100882063; called by muse, mutect2
- FOXH1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100023820; called by muse, mutect2, varscan2
- FOXO1 | c.1159T>A p.L387I | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV101092011; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100598907; called by muse, mutect2, varscan2
- FUT6 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99744643; called by muse, mutect2, varscan2
- FUZ | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as rs528957343, COSV100571161; called by muse, varscan2
- FYB1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV60956196; called by muse, mutect2, varscan2
- FYB1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100685526; called by muse, mutect2, varscan2
- FYB2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV100599568; called by muse, mutect2, varscan2
- G2E3 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99249671; called by muse, mutect2, varscan2
- GABRA1 | c.1058A>C p.K353T | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.229); catalogued as COSV99195951; called by muse, mutect2, varscan2
- GABRA2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1480056834, COSV100734110, COSV62916543; called by muse, mutect2, varscan2
- GABRP | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs770947239, COSV54665494; called by muse, mutect2, varscan2
- GALC | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99729808; called by muse, mutect2, varscan2
- GALC | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as rs1404226903, COSV54326070; called by muse, mutect2, varscan2
- GAPVD1 | c.2788C>T p.P930S (on ENST00000394104; = p.P957S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.15); catalogued as COSV99783261; called by muse, mutect2, varscan2
- GBE1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs183019204, COSV101450122; called by muse, mutect2, varscan2
- GBP7 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs996355331, COSV99643162; called by muse, mutect2, varscan2
- GDPD1 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343908955, COSV99405104; called by muse, mutect2, varscan2
- GGT1 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs774876985, COSV50644435; called by muse, mutect2
- GGTLC2 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV101312231; called by muse, mutect2
- GIMAP7 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100543672; called by muse, mutect2, varscan2
- GJA10 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101005361; called by muse, mutect2, varscan2
- GJA5 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99605574; called by muse, mutect2, varscan2
- GJD2 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.859); catalogued as COSV51749626, COSV99290770; called by muse, mutect2, varscan2
- GK2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1225278704, COSV100725968, COSV62627961; called by muse, mutect2, varscan2
- GLB1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as CM106677, COSV100257378; called by muse, mutect2, varscan2
- GLE1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs772765696, COSV100012594; called by muse, mutect2, varscan2
- GLT6D1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348575817, COSV100874538; called by muse, mutect2, varscan2
- GMEB1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs544728720, COSV99603246; called by muse, mutect2, varscan2
- GPATCH8 | c.2938C>T p.H980Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100132685; called by muse, mutect2, varscan2
- GPD1 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866143632, COSV56548002; called by muse, mutect2, varscan2
- GPR55 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as COSV101235857; called by muse, mutect2, varscan2
- GPRC6A | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100114418; called by muse, mutect2, varscan2
- GPRC6A | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs149855100, COSV59951776, COSV59955288; called by muse, mutect2, varscan2
- GPRIN1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99991670; called by muse, mutect2, varscan2
- GREB1 | c.3346C>T p.P1116S | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.302); catalogued as COSV99303000; called by muse, mutect2, varscan2
- GRIN2B | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101663057; called by muse, mutect2, varscan2
- GRIN3A | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100701538, COSV62460601; called by muse, mutect2, varscan2
- GRK1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as rs1321308907, COSV100175360; called by muse, mutect2, varscan2
- GRM1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as COSV99266490; called by muse, mutect2, varscan2
- GSTCD | c.1657C>T p.P553S (on ENST00000360505 / NM_001031720.3; = p.P466S on NM_024751.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756961867, COSV100853844; called by muse, mutect2, varscan2
- GTF2IRD1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99734794; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782062310, COSV99734795; called by muse, mutect2, varscan2
- GUCY1A1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as rs772453526, COSV56649256, COSV56653947; called by muse, mutect2, varscan2
- GUCY2D | c.2769G>A p.K923= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99644019; called by muse, mutect2, varscan2
- GYS2 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99679815; called by muse, mutect2, varscan2
- GZMB | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99362363; called by muse, mutect2, varscan2
- H4C3 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV100619557; called by muse, mutect2, varscan2
- HACE1 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as COSV53509010; called by muse, mutect2, varscan2
- HAPLN1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1365614504, COSV99164952; called by muse, mutect2, varscan2
- HAVCR1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761993425, COSV59403238; called by muse, mutect2, varscan2
- HBG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs151258456, COSV57963441; called by muse, mutect2, varscan2
- HCN1 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV57522708, COSV57536689; called by muse, mutect2, varscan2
- HECTD4 | c.4694C>T p.S1565L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as COSV101106753; called by muse, mutect2, varscan2
- HEPH | c.128G>A p.G43E (on ENST00000343002; = p.G97E on NM_138737.5) | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV100294130; called by muse, mutect2, varscan2
- HEPHL1 | c.2330G>A p.W777* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as COSV100243984; called by muse, mutect2, varscan2
- HHIPL2 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 46/113 reads (41%) | catalogued as rs1359417135, COSV100596899; called by muse, mutect2, varscan2
- HIC2 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101335590; called by muse, mutect2, varscan2
- HLA-DQB1 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749771434, COSV100891266; called by muse, mutect2
- HNRNPLL | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV55367209; called by muse, mutect2, varscan2
- HOXA13 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV99763621; called by muse, mutect2, varscan2
- HRG | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772500244, COSV99214815; called by muse, mutect2, varscan2
- HSD3B1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs587670461, COSV99347965; called by muse, mutect2, varscan2
- HSPA12B | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.402); catalogued as COSV99654022; called by muse, mutect2, varscan2
- HTR2A | c.490A>G p.M164V | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV101096705; called by muse, mutect2, varscan2
- HTR3A | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776176400, COSV100248445; called by muse, mutect2, varscan2
- HTRA1 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV100934757; called by muse, mutect2, varscan2
- HTT | c.5314T>G p.Y1772D | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100750819; called by muse, mutect2, varscan2
- HUNK | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs184706666, COSV54228396; called by muse, mutect2, varscan2
- HYDIN | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267604623, COSV55485377; called by muse, mutect2, varscan2
- IFITM3 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100068250; called by muse, mutect2, varscan2
- IFNLR1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336937930, COSV100552183; called by muse, mutect2, varscan2
- IGKV1-16 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs762334632; called by muse, varscan2
- IGKV1-17 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs562093749; called by muse, mutect2, varscan2
- IGKV1-5 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs773635617; called by muse, mutect2, varscan2
- IGSF10 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.122); catalogued as rs779928369, COSV99180455; called by muse, mutect2, varscan2
- IGSF10 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV99180464; called by muse, mutect2, varscan2
- IGSF22 | c.2672G>A p.G891E (on ENST00000319338; = p.G992E on NM_173588.4) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV55010532; called by muse, mutect2, varscan2
- IL15 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.957); catalogued as COSV99650549; called by muse, mutect2, varscan2
- IL1RL1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.062); catalogued as COSV52114722; called by muse, mutect2, varscan2
- IL1RL1 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.167); catalogued as COSV99294152; called by muse, mutect2, varscan2
- IL1RL2 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99960713; called by muse, mutect2, varscan2
- IL20RA | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 57/73 reads (78%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs866902353, COSV100360004; called by muse, mutect2, varscan2
- INSR | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100252352; called by muse, mutect2, varscan2
- INTS6L | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 125/150 reads (83%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV100878120; called by muse, mutect2, varscan2
- IPO9 | c.326T>A p.I109N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100843447; called by muse, mutect2, varscan2
- IQCC | c.310A>C p.K104Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV99356605; called by muse, mutect2, varscan2
- IQGAP1 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99185047; called by muse, mutect2, varscan2
- IQSEC3 | c.3016C>A p.P1006T (on ENST00000538872 / NM_001170738.2; = p.P703T on NM_015232.1) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100407261; called by muse, mutect2, varscan2
- ITGA7 | c.2503G>A p.E835K (on ENST00000555728; = p.E791K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57698261; called by muse, mutect2, varscan2
- ITGA8 | c.2822G>A p.G941E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100959246, COSV100959646; called by muse, mutect2, varscan2
- ITLN1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100406243; called by muse, mutect2, varscan2
- ITLN2 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1453169516, COSV100600720; called by muse, mutect2, varscan2
- ITPR3 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65406795; called by muse, mutect2, varscan2
- ITPR3 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100966926; called by muse, mutect2, varscan2
- JCAD | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100948389, COSV100948391, COSV64758686; called by muse, mutect2, varscan2
- JPH2 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100881742; called by muse, mutect2, varscan2
- JPH3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1183344242, COSV52472063; called by muse, mutect2, varscan2
- KBTBD12 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1425591917, COSV100675448, COSV100675526; called by muse, mutect2, varscan2
- KCNA1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.045); catalogued as rs1565433579, COSV101230277; called by muse, mutect2
- KCNA2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60371617; called by muse, mutect2, varscan2
- KCNA4 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs767562204, COSV60251065, COSV60251951; called by muse, mutect2, varscan2
- KCNB1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as COSV65571078; called by muse, mutect2, varscan2
- KCND3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV100137540; called by muse, mutect2, varscan2
- KCNF1 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99705731; called by muse, mutect2, varscan2
- KCNH7 | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs904190475, COSV100148162, COSV59802393; called by muse, mutect2, varscan2
- KCNH7 | c.465G>A p.R155= | Splice Region (SNP) | VAF 24/43 reads (56%) | catalogued as COSV59794266; called by muse, mutect2, varscan2
- KCNJ6 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV99899902; called by muse, mutect2, varscan2
- KCNK18 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs552800446, COSV57971233; called by muse, mutect2, varscan2
- KCNK5 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs747825371, COSV100851858; called by muse, mutect2, varscan2
- KCNMA1 | c.2285C>T p.S762L (on ENST00000286628 / NM_001161352.2; = p.S704L on NM_002247.4) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99697695, COSV99698594; called by muse, mutect2, varscan2
- KCTD3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as rs1410604541, COSV52065271; called by muse, mutect2, varscan2
- KDM4D | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV100624275; called by muse, mutect2, varscan2
- KEL | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100787106; called by muse, mutect2, varscan2
- KIAA0586 | c.3694G>A p.G1232R (on ENST00000619416 / NM_001244190.2; = p.G1171R on NM_014749.5) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708216; called by muse, mutect2, varscan2
- KIAA1210 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.136); catalogued as COSV101274185; called by muse, mutect2, varscan2
- KIAA1217 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV100286706; called by muse, mutect2
- KIAA1614 | c.2315C>T p.S772F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100851214; called by muse, mutect2
- KIF22 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99361179; called by muse, mutect2, varscan2
- KIF22 | c.1677G>A p.K559= | Splice Region (SNP) | VAF 33/82 reads (40%) | catalogued as rs1397979573, COSV99361181; called by muse, mutect2, varscan2
- KIF26B | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100832542; called by muse, mutect2, varscan2
- KIR3DL1 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); catalogued as COSV58490215; called by muse, mutect2
- KIR3DL2 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.229); catalogued as COSV99552103; called by muse, mutect2, varscan2
- KLHL38 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100384419; called by muse, mutect2, varscan2
- KLHL4 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64139282, COSV64140562, COSV64142481; called by muse, mutect2, varscan2
- KNDC1 | c.1184A>C p.Q395P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100464984; called by muse, mutect2, varscan2
- KNG1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV99405567, COSV99405592; called by muse, mutect2, varscan2
- KRT1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1280274048, COSV52869236; called by muse, mutect2, varscan2
- KRT37 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs1438193779, COSV99845508; called by muse, mutect2, varscan2
- KRT4 | c.1002C>T p.V334= | Splice Region (SNP) | VAF 17/74 reads (23%) | catalogued as COSV99542976; called by muse, mutect2, varscan2
- KRT84 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1283454012, COSV57771418; called by muse, mutect2, varscan2
- KRT9 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs780378178, COSV99879218; called by muse, varscan2
- KYNU | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs753701829, COSV99933334; called by muse, mutect2, varscan2
- L3MBTL4 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766842361, COSV53116535, COSV53123012, COSV53141398; called by muse, mutect2, varscan2
- LAMA1 | c.5308G>A p.E1770K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as COSV101056567; called by muse, mutect2, varscan2
- LAMA4 | c.3281G>A p.G1094E (on ENST00000230538 / NM_001105206.3; = p.G1087E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV100038543; called by muse, mutect2, varscan2
- LAMB3 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs149360787, COSV100620372; called by muse, mutect2, varscan2
- LCE5A | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.85); PolyPhen possibly damaging (0.447); catalogued as COSV100524261; called by muse, mutect2, varscan2
- LCT | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99929597; called by muse, mutect2, varscan2
- LDB2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453828; called by muse, mutect2, varscan2
- LGR6 | c.213G>A p.L71= (on ENST00000367278 / NM_001017403.1; = p.R19= on NM_021636.3) | Splice Region (SNP) | VAF 33/118 reads (28%) | catalogued as COSV99707089; called by muse, mutect2, varscan2
- LGSN | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1378448143, COSV101040542; called by muse, mutect2, varscan2
- LIFR | c.3245G>A p.G1082E | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as rs775530423, COSV54692530; called by muse, mutect2, varscan2
- LIG1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV54397373; called by muse, mutect2, varscan2
- LILRB1 | c.1276G>A p.A426T (on ENST00000427581; = p.A390T on NM_006669.6) | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs756518809, COSV100207340; called by muse, mutect2, varscan2
- LMLN | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1391144823, COSV100218618; called by muse, mutect2, varscan2
- LOXL2 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV101207912; called by muse, mutect2
- LPAR4 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101425129; called by muse, mutect2, varscan2
- LPGAT1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878142; called by muse, mutect2, varscan2
- LRFN2 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as COSV57833322; called by muse, varscan2
- LRP1 | c.5470C>T p.R1824W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99675999; called by muse, mutect2, varscan2
- LRP2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs774803256, COSV99788697; called by muse, mutect2, varscan2
- LRP5 | c.3976C>T p.R1326C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs931097381, COSV53723809, COSV99592107; called by muse, varscan2
- LRRC4C | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538456; called by muse, mutect2
- LRRC66 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV100602983; called by muse, mutect2, varscan2
- LRRC7 | c.4144G>A p.G1382R (on ENST00000651989 / NM_001370785.2; = p.G1302R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs754926067, COSV50439136; called by muse, mutect2, varscan2
- LRRCC1 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs750034546, COSV64483242, COSV64484403; called by muse, mutect2, varscan2
- LRRIQ1 | c.2200C>T p.L734F | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV101280506; called by muse, mutect2, varscan2
- LRTM1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 95/224 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV55513864; called by muse, mutect2, varscan2
- LSG1 | c.1275G>A p.Q425= | Splice Region (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99503262; called by muse, mutect2
- LYSMD4 | c.613C>T p.P205S (on ENST00000409796 / NM_001284417.2; = p.P206S on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV100230625; called by muse, mutect2
- LYST | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101089612; called by muse, mutect2, varscan2
- LYZL1 | c.525G>A p.W175* (on ENST00000375500; = p.W129* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as rs1203873347, COSV100973642; called by muse, mutect2, varscan2
- MACROH2A2 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100951954; called by muse, mutect2, varscan2
- MAGEB1 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.123); catalogued as COSV66775832; called by muse, mutect2, varscan2
- MAGEC1 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 89/105 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs763285093, COSV53567836, COSV53577256; called by muse, mutect2, varscan2
- MAGI3 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs1443502538, COSV100289284, COSV56841188; called by muse, mutect2, varscan2
- MAML1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs202236629, COSV99483153; called by muse, mutect2, varscan2
- MAP2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); catalogued as COSV52306260, COSV99560212; called by muse, mutect2, varscan2
- MAP3K21 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs753079246, COSV64045846; called by muse, mutect2, varscan2
- MAP3K21 | c.2459C>T p.P820L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64041466; called by muse, mutect2, varscan2
- MARCHF1 | c.181G>A p.G61R (on ENST00000274056; = p.G44R on NM_017923.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.154); catalogued as rs1267123486, COSV99921228, COSV99923090; called by muse, mutect2, varscan2
- MARF1 | c.2291T>A p.L764* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100705988; called by muse, mutect2, varscan2
- MDFI | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100025659; called by mutect2, varscan2
- MED12L | c.6110C>T p.P2037L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV99853341; called by muse, mutect2, varscan2
- MED13 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101181113, COSV67263219; called by muse, mutect2, varscan2
- MED13 | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101181115; called by muse, mutect2, varscan2
- MED13L | c.6347C>T p.S2116L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs774432060, COSV56129581; called by muse, mutect2, varscan2
- MEFV | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV99560923; called by muse, mutect2
- MEGF8 | c.7378A>T p.N2460Y (on ENST00000251268 / NM_001271938.2; = p.N2393Y on NM_001410.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1457891573, COSV99236586; called by muse, mutect2
- METTL22 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.131); catalogued as rs202207266, COSV50837373; called by muse, varscan2
- MGAM | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074020; called by muse, mutect2, varscan2
- MIA2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs200876456, COSV54481706; called by muse, mutect2, varscan2
- MIOX | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as rs745820038, COSV99326919; called by muse, mutect2, varscan2
- MKI67 | c.7388C>T p.S2463F | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV64077627; called by muse, mutect2
- MKX | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772891422, COSV65391454; called by muse, varscan2
- MKX | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV101008782; called by muse, varscan2
- MMP17 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV62181738; called by muse, mutect2, varscan2
- MMP24 | c.1697G>A p.W566* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99863876; called by muse, mutect2, varscan2
- MMP3 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1555005682, COSV55407536; called by muse, mutect2, varscan2
- MMS22L | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773047071, COSV51524732; called by muse, mutect2, varscan2
- MPP6 | c.884-1G>A p.X295_splice | Splice Site (SNP) | VAF 22/92 reads (24%) | catalogued as rs866018563, COSV56040308, COSV99757546; called by muse, mutect2, varscan2
- MPP7 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs991808026, COSV61735201; called by muse, mutect2, varscan2
- MRGPRX1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100246014; called by muse, mutect2, varscan2
- MRPL37 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100289239; called by muse, mutect2, varscan2
- MSH3 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs779180469, COSV99434046; called by muse, varscan2
- MTCL1 | c.2072G>A p.G691E (on ENST00000306329 / NM_001378206.1; = p.G331E on NM_015210.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); catalogued as COSV100094673; called by muse, mutect2, varscan2
- MTRR | c.773C>T p.S258L (on ENST00000264668; = p.S231L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs201557658; called by muse, mutect2, varscan2
- MTTP | c.2384C>G p.S795C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); catalogued as COSV99645225; called by muse, mutect2, varscan2
- MUC16 | c.27067C>T p.P9023S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.196); catalogued as COSV101200039; called by muse, mutect2, varscan2
- MUC16 | c.18161C>T p.S6054F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV101199307, COSV67456239; called by muse, mutect2, varscan2
- MUC16 | c.10823G>A p.G3608E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.028); catalogued as COSV101200040; called by muse, mutect2, varscan2
- MUC16 | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV101200041; called by muse, mutect2, varscan2
- MUC17 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100073546; called by muse, mutect2, varscan2
- MUC21 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.303); catalogued as rs267600948, COSV66221697; called by muse, mutect2, varscan2
- MUC4 | c.12959C>T p.P4320L (on ENST00000463781 / NM_018406.7; = p.P84L on NM_004532.6) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs768070466, COSV57765496; called by muse, mutect2
- MUSK | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99504395; called by muse, mutect2, varscan2
- MVB12B | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1163803026, COSV100752907; called by muse, mutect2, varscan2
- MYH1 | c.849A>C p.E283D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99876070; called by muse, mutect2, varscan2
- MYH1 | c.531C>T p.I177= | Splice Region (SNP) | VAF 42/97 reads (43%) | catalogued as rs1233154268, COSV56853585; called by muse, mutect2, varscan2
- MYH10 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52605333; called by muse, mutect2, varscan2
- MYH2 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368304404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV55449845, COSV99820257; called by muse, mutect2, varscan2
- MYH4 | c.3150G>A p.M1050I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99701391; called by muse, mutect2, varscan2
- MYH6 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100676644; called by muse, mutect2, varscan2
- MYH7 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as CM122332, COSV100806152, COSV100806164; called by muse, mutect2, varscan2
- MYLK2 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV65658508; called by muse, mutect2, varscan2
- MYO16 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1200275190, COSV51779265; called by muse, mutect2, varscan2
- MYO18B | c.6934G>A p.E2312K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV59136218; called by muse, mutect2, varscan2
- MYO18B | c.7060C>T p.L2354F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100123811; called by muse, mutect2, varscan2
- MYO5B | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99545162; called by muse, mutect2, varscan2
- MYO5B | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1338751420, COSV53232754; called by muse, mutect2, varscan2
- MYO5B | c.2594C>T p.T865I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs775815528, COSV99545169; called by mutect2, varscan2
- MYO7B | c.1395T>G p.F465L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV101268205; called by muse, mutect2, varscan2
- MYOM1 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765967318, COSV55301999, COSV99866876; called by muse, mutect2, varscan2
- MYOM2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as rs758004464, COSV100037574; called by muse, mutect2, varscan2
- MYOM2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50768090; called by muse, mutect2, varscan2
- MYPN | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100590035; called by muse, mutect2, varscan2
- N4BP2 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770639357, COSV54702631, COSV54703786; called by muse, mutect2, varscan2
- NALCN | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs866059112, COSV51919514; called by muse, mutect2
- NASP | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1031446184, COSV100601834; called by muse, mutect2, varscan2
- NAV3 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs945164074, COSV57072562; called by muse, mutect2, varscan2
- NCOA1 | c.3100C>T p.P1034S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs199500142, COSV99946193; called by muse, mutect2, varscan2
- NDST4 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99996635; called by muse, mutect2, varscan2
- NDST4 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as COSV52126783, COSV99996639; called by muse, mutect2, varscan2
- NEB | c.19166G>A p.R6389K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV99423790; called by muse, mutect2, varscan2
- NEB | c.7750C>T p.Q2584* | Nonsense Mutation (SNP) | VAF 149/355 reads (42%) | catalogued as COSV99423793; called by muse, mutect2, varscan2
- NEBL | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101009226; called by muse, mutect2, varscan2
- NEFH | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100151603; called by muse, mutect2, varscan2
- NEK9 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as COSV99464131; called by muse, mutect2, varscan2
- NEXMIF | c.3383G>A p.G1128E | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV99280932; called by muse, mutect2, varscan2
- NEXMIF | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV99280937; called by muse, varscan2
- NGEF | c.1709A>C p.E570A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99889373; called by muse, mutect2
- NGEF | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs1399414798, COSV99889379; called by muse, mutect2, varscan2
- NGEF | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99889384; called by muse, mutect2, varscan2
- NKAPL | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV100642526; called by muse, mutect2, varscan2
- NKX6-2 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs768786455, COSV100888344; called by muse, mutect2, varscan2
- NLGN3 | c.1295C>T p.S432F (on ENST00000358741 / NM_181303.2; = p.S412F on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV62441871, COSV62442750; called by muse, mutect2, varscan2
- NLRP11 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100789750; called by muse, mutect2, varscan2
- NLRP4 | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs145150483, COSV56715072; called by muse, mutect2, varscan2
- NLRP8 | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV52591799; called by muse, mutect2, varscan2
- NOC4L | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762665769, COSV57958914; called by muse, varscan2
- NOC4L | c.1210C>T p.L404F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1447111047, COSV100400119; called by muse, varscan2
- NOS1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.75); PolyPhen benign (0.212); catalogued as COSV100500700; called by muse, mutect2, varscan2
- NOS2 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs1412597971, COSV58228416; called by muse, mutect2, varscan2
- NPAP1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.542); catalogued as COSV100275476; called by muse, mutect2, varscan2
- NPY4R | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100966173; called by muse, mutect2, varscan2
- NRXN1 | c.3146T>G p.F1049C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100455386; called by muse, mutect2, varscan2
- NRXN1 | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs1238347322, COSV101277638; called by muse, mutect2, varscan2
- NSD2 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs943227424, COSV100373391; called by muse, mutect2, varscan2
- NUAK2 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as rs1415944578, COSV100904075; called by muse, mutect2, varscan2
- NUGGC | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374601562; called by muse, mutect2, varscan2
- NUP210 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV99596273; called by muse, mutect2, varscan2
- NUP210L | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.311); catalogued as COSV99668201; called by muse, mutect2, varscan2
- NVL | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs866683945, COSV55869764, COSV55874438; called by muse, mutect2
- NYNRIN | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101230605; called by muse, mutect2, varscan2
- OAZ1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as rs1376249808, COSV100457314; called by muse, mutect2
- OAZ1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs1476631218, COSV100457316; called by muse, mutect2
- OBSCN | c.11489C>T p.P3830L | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1475387400, COSV99479065; called by muse, mutect2, varscan2
- OBSCN | c.12490G>A p.G4164R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765652515, COSV99479070; called by muse, mutect2, varscan2
- OLFM3 | c.526G>A p.E176K (on ENST00000338858 / NM_001288821.1; = p.E156K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100129599; called by muse, mutect2, varscan2
- OPLAH | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as rs1428890538, COSV70677867; called by muse, mutect2
- OR10A6 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100564294; called by muse, mutect2, varscan2
- OR10K2 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1433599585, COSV100149658, COSV59221726; called by muse, mutect2, varscan2
- OR11H1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV99421825; called by mutect2, varscan2
- OR14J1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs1265139771, COSV65845654; called by muse, mutect2, varscan2
- OR1A2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101126355; called by muse, mutect2, varscan2
- OR1F1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100484440; called by muse, mutect2, varscan2
- OR1M1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101447563; called by muse, mutect2, varscan2
- OR1M1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.776); catalogued as COSV101447564; called by muse, mutect2, varscan2
- OR2M7 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100522570; called by muse, mutect2
- OR2M7 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs752989471, COSV100522572; called by muse, mutect2
- OR2T1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1009832433, COSV63542620; called by muse, mutect2
- OR2T34 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100170381; called by muse, mutect2, varscan2
- OR2T6 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1205407324, COSV100861568; called by muse, mutect2, varscan2
- OR2Z1 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as rs1555756718, COSV100136440; called by muse, mutect2, varscan2
- OR4C11 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100155345; called by muse, mutect2, varscan2
- OR4C15 | c.453G>A p.M151I (on ENST00000314644; = p.M97I on NM_001001920.2) | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as rs763726329, COSV58951556; called by muse, mutect2, varscan2
- OR4N2 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1176764184, COSV60054808; called by muse, mutect2, varscan2
- OR51A7 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV63788220; called by muse, mutect2, varscan2
- OR51F1 | c.127T>A p.F43I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100598793; called by muse, mutect2, varscan2
- OR51G2 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58992241, COSV58992948; called by muse, mutect2, varscan2
- OR51I1 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201278585; called by muse, mutect2, varscan2
- OR51M1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100150255; called by muse, mutect2, varscan2
- OR51V1 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs987853856, COSV100343384; called by muse, mutect2, varscan2
- OR52A5 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV56614894; called by muse, mutect2, varscan2
- OR52A5 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56616891; called by muse, mutect2, varscan2
- OR52L1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.46); catalogued as COSV100176188; called by muse, mutect2, varscan2
- OR52N5 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100399704; called by muse, mutect2, varscan2
- OR5K3 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs776712584, COSV101051650; called by muse, mutect2, varscan2
- OR5R1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV100393464; called by muse, mutect2, varscan2
- OR6K6 | c.332C>T p.S111F (on ENST00000368144; = p.S87F on NM_001005184.1) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV63744219, COSV63744589; called by muse, mutect2, varscan2
- OR7A10 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99932463; called by muse, mutect2, varscan2
- OR7D4 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1568329276, COSV58071636; called by muse, mutect2, varscan2
- OR7D4 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs763416711, COSV100432749; called by muse, mutect2, varscan2
- OR7E24 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774763866, COSV71702387; called by muse, mutect2, varscan2
- OR8J3 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1218309565, COSV56881903; called by muse, mutect2, varscan2
- OR9A2 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV63306704; called by muse, mutect2, varscan2
- OSER1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV99667362; called by muse, mutect2, varscan2
- OTOP1 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs754499989, COSV99587731; called by muse, mutect2, varscan2
- OTX2 | c.772G>A p.D258N (on ENST00000408990 / NM_172337.3; = p.D266N on NM_021728.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59766644; called by muse, mutect2, varscan2
- OTX2 | c.608C>T p.S203L (on ENST00000408990 / NM_172337.3; = p.S211L on NM_021728.4) | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV59767727; called by muse, mutect2, varscan2
- OVCH1 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99759770; called by muse, mutect2, varscan2
- P3H2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs771139030, COSV100077790; called by muse, mutect2, varscan2
- P3H2 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV60021136; called by muse, mutect2, varscan2
- PAFAH2 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs12410711, COSV65339564; called by muse, mutect2, varscan2
- PAK5 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225133285, COSV62024283; called by muse, mutect2, varscan2
- PAK5 | c.1370A>T p.E457V | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100781378; called by muse, varscan2
- PAK5 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1210292896, COSV62020757; called by muse, varscan2
- PAMR1 | c.1039C>T p.R347* (on ENST00000619888 / NM_001001991.3; = p.R364* on NM_015430.4) | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as rs774065416, COSV99552688; called by muse, mutect2, varscan2
- PAN2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769742340, COSV99228310; called by muse, mutect2, varscan2
- PARD3 | c.3596T>C p.V1199A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100632190; called by muse, mutect2, varscan2
- PARP15 | c.1556C>T p.S519F (on ENST00000464300 / NM_001113523.3; = p.S285F on NM_152615.2) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV100117088; called by muse, mutect2, varscan2
- PARP8 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV55862781; called by muse, mutect2, varscan2
- PARP8 | c.2460C>T p.F820= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as rs1225789516, COSV55856469, COSV55866387; called by muse, mutect2, varscan2
- PCDH12 | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99189029; called by muse, mutect2, varscan2
- PCDH15 | c.4912G>A p.E1638K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs867754850, COSV57309177; called by muse, mutect2, varscan2
- PCDH18 | c.2873C>A p.P958H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100787338; called by muse, mutect2, varscan2
- PCDHA10 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56488259; called by muse, mutect2, varscan2
- PCDHA11 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs782726122, COSV56491168; called by muse, mutect2, varscan2
- PCDHA13 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV99166569; called by muse, mutect2, varscan2
- PCDHA3 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as COSV100793511; called by muse, mutect2, varscan2
- PCDHA6 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.013); catalogued as COSV100972312; called by muse, mutect2, varscan2
- PCDHA7 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.752); catalogued as rs782422719, COSV65345501; called by muse, varscan2
- PCDHB1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs1254111938, COSV60629676; called by muse, mutect2, varscan2
- PCDHB1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60629644; called by muse, mutect2, varscan2
- PCDHB13 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV53395192; called by muse, mutect2, varscan2
- PCDHB3 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.111); catalogued as COSV99165320; called by muse, mutect2, varscan2
- PCDHB4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV99522233; called by muse, mutect2, varscan2
- PCDHB7 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50798706; called by muse, mutect2, varscan2
- PCDHB7 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV50768443; called by muse, varscan2
- PCDHB8 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 51/389 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.334); catalogued as COSV99177025; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGA2 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.208); catalogued as COSV99539233; called by muse, mutect2, varscan2
- PCDHGA7 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99539237; called by muse, mutect2, varscan2
- PCED1B | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.333); catalogued as COSV101423651; called by muse, mutect2, varscan2
- PCLO | c.6794C>T p.S2265F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs1185436297, COSV61621473; called by muse, mutect2, varscan2
- PDE4DIP | c.3841G>A p.G1281S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519567; called by muse, mutect2, varscan2
- PDE6A | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs754762237, COSV54924278; called by muse, mutect2, varscan2
- PDZD2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1303175012, COSV99225197; called by muse, mutect2, varscan2
- PDZD2 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375345119, COSV56871868, COSV99224766; called by muse, mutect2, varscan2
- PEG3 | c.3821G>A p.R1274K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as COSV55626549, COSV55629647, COSV99689157; called by muse, mutect2, varscan2
- PEG3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771803012, COSV55651668, COSV99689622; called by muse, mutect2, varscan2
- PENK | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV100152343; called by muse, mutect2, varscan2
- PEX5 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs751937990, COSV99870968; called by muse, varscan2
- PGPEP1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763233991, COSV99416575; called by muse, mutect2, varscan2
- PHF1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100992631; called by muse, mutect2, varscan2
- PHOX2A | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996285; called by muse, mutect2, varscan2
- PIWIL2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.172); catalogued as rs756843324; called by muse, mutect2, varscan2
- PKDREJ | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs758054596, COSV99478966; called by muse, mutect2, varscan2
- PKHD1L1 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV65743379; called by muse, mutect2, varscan2
- PKHD1L1 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1296298151, COSV65752415; called by muse, mutect2
- PKP2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV50739019; called by muse, mutect2, varscan2
- PKP4 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101081018; called by muse, mutect2, varscan2
- PLA2G7 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV99221408; called by muse, mutect2, varscan2
- PLAUR | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99655196; called by muse, mutect2, varscan2
- PLCE1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs201512392, COSV53343117; called by muse, mutect2, varscan2
- PLCE1 | c.3997C>T p.L1333F | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773151394, COSV99595158; called by muse, mutect2, varscan2
- PLCL2 | c.1790G>A p.G597E (on ENST00000615277 / NM_001144382.2; = p.G471E on NM_015184.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV101196759; called by muse, mutect2, varscan2
- PLCXD3 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs746073648, COSV60610978, COSV60618210; called by muse, mutect2, varscan2
- PLCZ1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV56852718; called by muse, mutect2, varscan2
- PLEK | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99311001; called by muse, mutect2, varscan2
- PLEKHA4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs780282132, COSV99612634; called by muse, mutect2, varscan2
- PLEKHO2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750368641, COSV60262096; called by muse, mutect2, varscan2
- PLXNA4 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100324538; called by muse, mutect2, varscan2
- PLXNB2 | c.3663G>A p.W1221* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100834085, COSV63781463; called by muse, mutect2
- PLXND1 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV100139824; called by muse, mutect2, varscan2
- PNP | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs1304437118, COSV64091978; called by muse, mutect2, varscan2
- PNPLA1 | c.1112C>T p.P371L (on ENST00000394571 / NM_001374623.1; = p.P276L on NM_173676.2) | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57235109; called by muse, mutect2, varscan2
- PON1 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99732323; called by muse, mutect2, varscan2
- PPFIA4 | c.2108C>T p.S703F (on ENST00000447715; = p.S704F on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV55311909; called by muse, mutect2, varscan2
- PPP1R10 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV100919851; called by muse, mutect2
- PPP1R18 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs1244871077, COSV99223737; called by muse, mutect2, varscan2
- PPP1R32 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV100087838; called by muse, mutect2, varscan2
- PPP3CA | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV100547733; called by muse, mutect2, varscan2
- PPP4R2 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99866110; called by muse, mutect2, varscan2
- PPRC1 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV99531711; called by muse, mutect2, varscan2
- PRAMEF12 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV63215850; called by muse, mutect2, varscan2
- PRAMEF12 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769755107, COSV63214663; called by muse, mutect2, varscan2
- PRAMEF4 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 61/168 reads (36%) | catalogued as COSV52437837, COSV99339868; called by muse, mutect2, varscan2
- PRAMEF7 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100435102; called by muse, mutect2, varscan2
- PRB4 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV54396145; called by muse, varscan2
- PRG4 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100798224; called by muse, mutect2, varscan2
- PRLHR | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99492807; called by muse, mutect2, varscan2
- PROSER1 | c.2545C>T p.L849F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100612826; called by muse, mutect2, varscan2
- PRR23B | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.242); catalogued as rs1379403110, COSV100271968, COSV100272091; called by muse, mutect2, varscan2
- PRR30 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV99574496; called by muse, mutect2, varscan2
- PRRC2A | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV100784586; called by muse, mutect2, varscan2
- PRRC2C | c.6707C>T p.S2236F (on ENST00000367742; = p.S2234F on NM_015172.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100145340; called by muse, mutect2
- PRUNE2 | c.7976C>T p.T2659I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100944651; called by muse, mutect2, varscan2
- PRUNE2 | c.5293G>A p.D1765N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); catalogued as COSV100944254, COSV100944652, COSV65037554; called by muse, mutect2, varscan2
- PSORS1C2 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99456105; called by muse, mutect2, varscan2
- PTH2R | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs373798724, COSV55914177; called by muse, mutect2, varscan2
- PTK7 | c.2014A>T p.I672F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV100030223; called by muse, mutect2, varscan2
- PTPN11 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100692706; called by muse, mutect2, varscan2
- PTPN6 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603654, COSV59684299; called by muse, mutect2, varscan2
- PTPRC | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs762236684, COSV100722711; called by muse, mutect2, varscan2
- PTPRC | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100722715; called by muse, mutect2, varscan2
- PTPRD | c.4021G>A p.E1341K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1456256399, COSV61986019; called by muse, mutect2, varscan2
- PTPRD | c.3266G>A p.G1089E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100645000; called by muse, mutect2, varscan2
- PTPRH | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as COSV99671067; called by muse, mutect2, varscan2
- PTPRK | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100951184; called by muse, mutect2, varscan2
- PWWP2B | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV100535822, COSV59452071; called by muse, mutect2, varscan2
- PXDNL | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177849906, COSV62480262; called by muse, mutect2, varscan2
- PXT1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.013); catalogued as COSV60317805; called by muse, mutect2, varscan2
- PYGO1 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV100114660; called by muse, mutect2, varscan2
- PZP | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs1158566092, COSV54354267; called by muse, mutect2, varscan2
- RAG1 | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100200926; called by muse, mutect2
- RANBP17 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.224); catalogued as COSV101206312, COSV66648860; called by muse, mutect2, varscan2
- RANBP3L | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56958296; called by muse, mutect2, varscan2
866 further variants in this file (295 protein-altering or splice-affecting, 523 silent, 48 other) are not listed here.
